Gene-level copy-number profile of tumor specimen SM-JU32Y from CPTAC case C208854, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen SM-JU32Y: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ad9bcd8c-18e1-4214-a4b1-49321ebdc8fa.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105214 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/c10b07a0-d7be-47c3-b865-6d7791e0b583

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 5,497; copy number 2: 50,595; copy number 3: 2,808; copy number 6: 5.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,402,932–1,406,442, 1 gene: NKX1-1.
- chr10:48,009,873–48,060,016, 3 genes: AGAP12P, RNA5SP315, BMS1P7.
- chr10:119,093,140–119,137,984, 2 genes: AL355598.2, DENND10.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:52,198,012–52,280,638, 3 genes, copy number 6: AC007333.2, AC007333.1, CASC22.
- chr16:52,436,772–52,437,474, 1 gene, copy number 6: AC007490.1.
- chr16:55,007,982–55,008,306, 1 gene, copy number 6: MTND5P34.

Autosomal genes at a single copy (total copy number 1): 2,641. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
